TCGA case TCGA-A7-A6VW — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/98e709e7-e195-4b37-9537-f6081affb609

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 48.0 years (17,539 days); Year of diagnosis: 2013; Method of diagnosis: Core Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin; Days to treatment start: 84 days; Days to treatment end: 134 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 148 days; Days to treatment end: 257 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 285 days; Days to treatment end: 331 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Indeterminate; Treatment anatomic sites: Breast.

Follow-up (2 entries)
- Days to follow up: 176 days; Disease response: Tumor Free.
- Days to follow up: 285 days; Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- ESR1 (IHC): Negative.
- PGR (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A7-A6VW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 370 mg.
  Slide TCGA-A7-A6VW-01A-02-TS2: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 18; Percent stromal cells: 22; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-A7-A6VW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A7-A6VW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Lumpectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Margin status: Close; Method initial path diagnosis: Core needle biopsy; Prospective collection: Yes; Retrospective collection: No; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 285 days; disease-specific survival: no event (censored), 285 days; progression-free interval: no event (censored), 285 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A7-A6VW-01A-21D-A33D-01): tumor purity 0.76, ploidy 1.72, whole-genome doublings 0.
